MMRF case MMRF_1342 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/0a0829db-261d-44ad-9910-784559c0f201

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 80 years; Vital status: Dead; Days to death: 778 days (2.1 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 80.8 years (29,514 days); ISS stage: III; Days to last known disease status: 778 days (2.1 years); Days to last follow up: 778 days (2.1 years).
   Treatment given: Therapeutic agents: Bortezomib + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 747 days (2.0 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 498 days (1.4 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 498 days (1.4 years); Days to treatment end: 672 days (1.8 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 672 days (1.8 years); Days to treatment end: 778 days (2.1 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 778.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -12 (ECOG 0): M Protein 1.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 53.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.722 mg/dL; Beta 2 Microglobulin 5.88 µg/mL; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 159 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 3.28 mmol/L; Albumin 42 g/L; Total Protein 9.9 g/dL; Glucose 5.78 mmol/L.
- Day 85 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.114 mg/dL; Immunoglobulin G 7.71 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.11 g/L; Hemoglobin 7.44 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 1.98 mmol/L; Albumin 35 g/L; Total Protein 6.7 g/dL; Glucose 6.82 mmol/L.
- Day 190 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.516 mg/dL; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 1.93 mmol/L; Albumin 34 g/L; Total Protein 6 g/dL; Glucose 5.56 mmol/L.
- Day 246 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.66 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.651 mg/dL; Immunoglobulin G 3.91 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 3.13 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 111 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.1 mmol/L; Albumin 34 g/L; Total Protein 6 g/dL; Glucose 4.84 mmol/L.
- Day 358 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.723 mg/dL; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 89 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.03 mmol/L; Albumin 35 g/L; Total Protein 6.3 g/dL; Glucose 5.12 mmol/L.
- Day 442 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.742 mg/dL; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 104 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.08 mmol/L; Albumin 36 g/L; Total Protein 6.5 g/dL; Glucose 5.5 mmol/L.
- Day 526 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.985 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.69 mg/dL; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 90 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.03 mmol/L; Albumin 31 g/L; Total Protein 6.2 g/dL; Glucose 5.67 mmol/L.
- Day 610 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.639 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.287 mg/dL; Lactate Dehydrogenase 3.82 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 110 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.08 mmol/L; Albumin 31 g/L; Total Protein 6.2 g/dL; Glucose 8.42 mmol/L.
- Day 721 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.052 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.055 mg/dL; Lactate Dehydrogenase 3.97 µkat/L; Hemoglobin 5.77 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 72 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 1.58 mmol/L; Albumin 23 g/L; Total Protein 4.9 g/dL; Glucose 6.16 mmol/L.
- Day 754 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.056 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.073 mg/dL; Hemoglobin 6.63 mmol/L; Leukocytes 9.6 ×10⁹/L; Absolute Neutrophil 8 ×10⁹/L; Platelets 125 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 1.83 mmol/L; Albumin 32 g/L; Total Protein 5.9 g/dL; Glucose 8.25 mmol/L.

Other clinical attributes
- Day -12: Weight: 69 kg; Height: 177 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1342_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -12 days.
- Sample MMRF_1342_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -12 days.
